Somatic mutation profile of tumor specimen TCGA-AR-A254-01A (aliquot TCGA-AR-A254-01A-21D-A167-09) from TCGA case TCGA-AR-A254, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 50.0 years (18,270 days).
Specimen TCGA-AR-A254-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaf9cfa2-36b3-4d08-8f61-1b2befb5f628.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A254-10A (Blood Derived Normal), aliquot TCGA-AR-A254-10A-01D-A167-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b40194d3-6d12-45d3-831b-d7bb7922408a

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 24, Silent 8, Nonsense Mutation 3, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.372C>A p.C124* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs1555526478, CM1210346, COSV52731101, COSV52944837; ClinVar: pathogenic; called by muse, varscan2
- ANKRD52 | c.2724A>T p.E908D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV57284225; called by muse, mutect2, varscan2
- BNIPL | c.503G>A p.W168* | Nonsense Mutation (SNP) | VAF 5/63 reads (8%) | catalogued as COSV99764783; called by muse, mutect2
- COQ7 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs188968280; called by muse, mutect2, varscan2
- DLX6 | c.391T>A p.Y131N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); catalogued as COSV50293670; called by muse, mutect2, varscan2
- DNAH5 | c.1781A>T p.E594V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV54223346; called by muse, mutect2, varscan2
- DSPP | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.906); catalogued as COSV99217931; called by muse, mutect2
- FAM171A1 | c.2305G>A p.V769I | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs1425442305, COSV65315873; called by muse, mutect2, varscan2
- MYH14 | c.2320G>T p.D774Y | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51817168; called by muse, mutect2, varscan2
- NOTCH1 | c.7321G>A p.A2441T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV53049671; called by muse, mutect2, varscan2
- PCDHB15 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50919444; called by muse, mutect2, varscan2
- PLCH1 | c.1372G>A p.E458K (on ENST00000340059 / NM_001130960.2; = p.E470K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV58196370; called by muse, mutect2, varscan2
- RASAL3 | c.2168G>A p.R723Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs201283291, COSV54607022; called by muse, mutect2, varscan2
- RTN2 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs570062973, COSV55593784; called by muse, mutect2, varscan2
- RUNX1 | c.557del p.Q186Rfs*24 (on ENST00000344691 / NM_001001890.3; = p.Q213Rfs*24 on NM_001754.5) | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as COSV55876091; called by mutect2, pindel, varscan2
- SLC29A3 | c.668C>A p.S223Y | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs757635412, COSV64385043; called by muse, varscan2
- SMCHD1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99862462; called by muse, mutect2
- SPTAN1 | c.4952G>A p.S1651N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); catalogued as COSV63987012; called by muse, mutect2, varscan2
- SPTAN1 | c.4953C>G p.S1651R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV63987016; called by muse, mutect2, varscan2
- SYNPO | c.2215G>A p.V739I (on ENST00000394243 / NM_001166208.2; = p.V495I on NM_007286.6) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.705); catalogued as COSV56940041; called by muse, mutect2, varscan2
- TNR | c.3340G>A p.D1114N | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV54884459; called by muse, mutect2, varscan2
- TRA2B | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.375); catalogued as rs758758553, COSV52025312; called by muse, mutect2, varscan2
- TRIM32 | c.551T>A p.V184D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV57775580; called by muse, mutect2, varscan2
- TRIM6 | c.830T>A p.M277K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV53476011; called by muse, mutect2, varscan2
- TSPEAR | c.1829C>G p.T610S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.017); catalogued as rs149397253; called by muse, mutect2
- VIRMA | c.5388T>G p.F1796L | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1245658751, COSV52584790; called by muse, mutect2, varscan2
- CNOT1 | c.4433_4434+34del p.X1478_splice | Splice Site (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel
- PTP4A3 | c.196G>T p.V66L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TADA2A | c.709C>T p.Q237* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
- CDC42EP3 | c.330G>A p.P110= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs140370566; called by muse, mutect2, varscan2
- CDC6 | c.855G>A p.E285= | Silent (SNP) | VAF 102/722 reads (14%) | catalogued as COSV52930451; called by muse, mutect2
- CNTNAP2 | c.2136C>T p.N712= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs187552025, COSV62144713, COSV62177655; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CTTNBP2 | c.1758G>A p.S586= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs776573193, COSV50390936; called by muse, mutect2, varscan2
- FNDC1 | c.453C>T p.T151= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs1368766012, COSV51937293; called by muse, mutect2, varscan2
- SLC29A3 | c.399C>A p.I133= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV64385040; called by muse, mutect2, varscan2
- SYNE1 | c.15312C>T p.H5104= (on ENST00000367255 / NM_182961.4; = p.H5033= on NM_033071.3) | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as rs144173352; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT3 | c.1335C>T p.A445= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs777995617, COSV58896449; called by muse, mutect2, varscan2
